Somatic mutation profile of tumor specimen TCGA-52-7810-01A (aliquot TCGA-52-7810-01A-11D-2122-08) from TCGA case TCGA-52-7810, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.9 years (22,241 days).
Specimen TCGA-52-7810-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49c71bdb-fbec-4478-9c0d-03cbb8f8ad5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-52-7810-10A (Blood Derived Normal), aliquot TCGA-52-7810-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ceab5ded-ddc7-424c-91f9-0ee9f990ffbe

The open-access MAF lists 459 somatic variants for this specimen: 338 protein-altering or splice-affecting, 113 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 282, Silent 113, Nonsense Mutation 36, Splice Site 6, Frame Shift Del 5, Intron 3, 3'UTR 3, Translation Start Site 3, Splice Region 2, Frame Shift Ins 2, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYBPC3 | c.2221del p.A741Qfs*13 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs730880650; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RAF1 | c.418A>C p.N140H | Missense Mutation (SNP) | VAF 143/180 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs730881009, COSV99312221; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.2165G>T p.R722L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100741736; called by mutect2, varscan2
- ABCA1 | c.5956C>G p.Q1986E | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs769126825, COSV101036739; called by muse, mutect2, varscan2
- ABCA13 | c.2665A>G p.I889V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as COSV101329988; called by muse, mutect2, varscan2
- ABCA13 | c.10859A>C p.E3620A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101446893; called by muse, mutect2, varscan2
- ABCC11 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100750639; called by muse, mutect2, varscan2
- ABCC12 | c.3707G>C p.R1236T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV100252397; called by muse, mutect2, varscan2
- ADAMTS7 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66309190; called by muse, mutect2, varscan2
- ADAMTS7 | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101183068; called by muse, mutect2, varscan2
- ADGRB3 | c.3325C>G p.L1109V | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV53240833, COSV99484373; called by muse, mutect2, varscan2
- ADSS2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs1308538165, COSV100836823; called by muse, mutect2, varscan2
- ALDH18A1 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV100973111; called by muse, mutect2, varscan2
- ALG8 | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100220026; called by muse, mutect2, varscan2
- ANK1 | c.2244C>A p.D748E | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV99224650; called by muse, mutect2, varscan2
- ANKDD1A | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs1167667376, COSV100731118; called by muse, mutect2, varscan2
- ANO1 | c.1127T>C p.I376T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs35101107; called by muse, mutect2, varscan2
- ANO4 | c.2474C>A p.A825D (on ENST00000392977 / NM_001286615.2; = p.A790D on NM_178826.4) | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); catalogued as COSV100152467; called by muse, mutect2, varscan2
- APOB | c.4952G>T p.G1651V | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99264705; called by muse, mutect2, varscan2
- ARHGAP6 | c.1754C>A p.T585K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as COSV100272625, COSV100273532; called by muse, mutect2, varscan2
- ARL13A | c.389A>C p.N130T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879006; called by muse, mutect2, varscan2
- ARMH3 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV100898859; called by muse, mutect2, varscan2
- ASIP | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100892067, COSV100892077, COSV66588816; called by muse, mutect2, varscan2
- ATM | c.8737G>C p.D2913H | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756899044, CM121262, COSV99587069, COSV99588756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A2 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100428503; called by muse, mutect2, varscan2
- ATXN3L | c.889C>A p.Q297K | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.101); catalogued as COSV101019349; called by muse, mutect2, varscan2
- BCAS4 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 35/52 reads (67%) | catalogued as COSV99372384; called by muse, mutect2, varscan2
- BCLAF3 | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503251; called by muse, mutect2, varscan2
- BCOR | c.4360C>T p.R1454W (on ENST00000378444 / NM_001123385.2; = p.R1420W on NM_017745.6) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs967564648, COSV60706519; called by muse, mutect2, varscan2
- BEND6 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100876801; called by muse, mutect2, varscan2
- BIRC6 | c.11231C>A p.S3744Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101428051; called by muse, mutect2, varscan2
- BLK | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs758798553; called by muse, mutect2
- BLZF1 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV100250564; called by muse, mutect2
- BMX | c.965G>C p.R322T | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100564391; called by muse, mutect2, varscan2
- BNC1 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100597036; called by muse, mutect2, varscan2
- C12orf71 | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101460494; called by muse, mutect2, varscan2
- C16orf46 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 35/104 reads (34%) | catalogued as COSV100215207; called by muse, mutect2, varscan2
- C1orf54 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs782739675, COSV51745641, COSV99290199; called by muse, mutect2, varscan2
- C20orf27 | c.208C>G p.L70V (on ENST00000379772 / NM_001258429.2; = p.L95V on NM_001039140.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.203); catalogued as COSV53925449, COSV99422098; called by muse, mutect2, varscan2
- C6orf58 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100314811; called by muse, mutect2, varscan2
- CA5A | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99990502; called by muse, mutect2, varscan2
- CADPS | c.2053G>A p.V685I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99337008; called by muse, mutect2
- CAVIN4 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV100293185; called by muse, mutect2, varscan2
- CCDC8 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100281974; called by muse, mutect2, varscan2
- CCDC88C | c.1266G>C p.Q422H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV101105417; called by muse, mutect2, varscan2
- CCT4 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101075127; called by muse, mutect2, varscan2
- CCT6A | c.623G>C p.R208T | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99303340; called by muse, mutect2, varscan2
- CDKL3 | c.1646G>T p.R549M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV99527746; called by muse, mutect2, varscan2
- CELF2 | c.1155G>T p.Q385H (on ENST00000416382 / NM_001025077.3; = p.Q398H on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); catalogued as COSV100257137; called by muse, mutect2, varscan2
- CFDP1 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52211856, COSV99033337; called by muse, mutect2, varscan2
- CFTR | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as rs199865300, COSV99134898; called by muse, mutect2, varscan2
- CLCN1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV100577900; called by muse, mutect2, varscan2
- CLEC12A | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs774737017, COSV100429450; called by muse, mutect2, varscan2
- CLEC4A | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99983588; called by muse, mutect2, varscan2
- CNKSR2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99667938; called by muse, mutect2, varscan2
- CNTNAP5 | c.542C>A p.A181D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV101443257; called by muse, mutect2, varscan2
- COG6 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100742723; called by mutect2, varscan2
- COL5A1 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs772379819, COSV65665347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.6916G>A p.E2306K (on ENST00000312481; = p.E2302K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99592516; called by muse, mutect2, varscan2
- COL6A5 | c.7051G>A p.E2351K (on ENST00000312481; = p.E2347K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs1198898069, COSV99592522; called by muse, mutect2, varscan2
- CPA3 | c.155G>A p.W52* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV99936030, COSV99936369; called by muse, mutect2, varscan2
- CPAMD8 | c.3858G>T p.W1286C (on ENST00000651564; = p.W1239C on NM_015692.5) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71595952, COSV71596739; called by muse, mutect2, varscan2
- CSMD2 | c.6774G>C p.K2258N | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV99587992; called by muse, mutect2, varscan2
- CTNND2 | c.1395C>G p.D465E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100474313; called by muse, mutect2, varscan2
- CTSC | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV99910587; called by muse, mutect2, varscan2
- CUBN | c.10307T>A p.F3436Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.721); catalogued as COSV100912356; called by muse, mutect2, varscan2
- CUL9 | c.7501G>C p.E2501Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV99335116; called by muse, mutect2, varscan2
- CXCR3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 35/63 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV101031582; called by muse, mutect2, varscan2
- DAPK1 | c.2372A>T p.Q791L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV100801437; called by muse, mutect2
- DCUN1D4 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV100584430; called by muse, mutect2, varscan2
- DENND4C | c.4597G>A p.A1533T (on ENST00000434457 / NM_001330640.2; = p.A1484T on NM_017925.7) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV100727376; called by muse, mutect2, varscan2
- DHX9 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as COSV100841322; called by muse, mutect2, varscan2
- DIDO1 | c.5090C>G p.S1697* | Nonsense Mutation (SNP) | VAF 51/104 reads (49%) | catalogued as COSV99825326; called by muse, mutect2, varscan2
- DLC1 | c.1042G>C p.D348H | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as rs781368372, COSV99362202; called by muse, mutect2, varscan2
- DNAH7 | c.7052C>T p.T2351I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100414526; called by muse, mutect2, varscan2
- DOP1B | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99535800; called by muse, mutect2, varscan2
- DYRK3 | c.1735C>G p.L579V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.046); catalogued as COSV100895653; called by muse, mutect2, varscan2
- EEA1 | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV100467362; called by muse, mutect2, varscan2
- EFNA3 | c.512C>G p.S171W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100860810; called by muse, mutect2, varscan2
- EIF4B | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV100016722; called by muse, mutect2, varscan2
- ENTHD1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100288607, COSV57317797; called by muse, mutect2, varscan2
- EPHA2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs754656950, COSV64452467; called by muse, mutect2, varscan2
- EPHA5 | c.2465C>A p.S822Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56632609, COSV99897693; called by muse, mutect2, varscan2
- EPHA5 | c.1676C>A p.T559N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56647091, COSV56647885, COSV99897695; called by muse, mutect2, varscan2
- ERG | c.1303A>G p.M435V (on ENST00000398919 / NM_001243428.1; = p.M411V on NM_004449.4) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99901525; called by muse, mutect2, varscan2
- EXOC3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/114 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); catalogued as COSV100155242; called by muse, mutect2, varscan2
- FAM104B | c.54C>A p.N18K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV100146010; called by muse, mutect2, varscan2
- FAM135B | c.2819C>A p.T940K | Missense Mutation (SNP) | VAF 114/165 reads (69%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV52708278, COSV99421433; called by muse, mutect2, varscan2
- FAM71B | c.1603A>T p.S535C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV100261973; called by muse, mutect2, varscan2
- FAM83F | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100328892; called by muse, mutect2, varscan2
- FAM9B | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100510936, COSV59119056; called by muse, mutect2, varscan2
- FANCD2 | c.3727G>C p.E1243Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV99810873; called by muse, mutect2, varscan2
- FAT3 | c.5737G>C p.E1913Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV99963949, COSV99968656; called by muse, mutect2, varscan2
- FBXO33 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.052); catalogued as COSV99980819; called by muse, mutect2, varscan2
- FBXO7 | c.1485G>T p.L495F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV99832560; called by muse, mutect2, varscan2
- FLG2 | c.4233G>T p.Q1411H | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV101165743; called by muse, mutect2, varscan2
- FLOT1 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58357344; called by muse, mutect2, varscan2
- FMR1 | c.1583G>C p.R528T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV99503140; called by muse, mutect2
- FOXF1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751560567, CM135701, COSV99296429; called by muse, mutect2, varscan2
- FRY | c.5750C>A p.A1917E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV100968979, COSV66576259; called by muse, mutect2, varscan2
- FRYL | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99976428; called by muse, mutect2, varscan2
- FUZ | c.319-2A>G p.X107_splice | Splice Site (SNP) | VAF 30/172 reads (17%) | catalogued as COSV100571071; called by muse, mutect2, varscan2
- GDF3 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs1402717557, COSV100325196; called by muse, mutect2, varscan2
- GDPD2 | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 62/85 reads (73%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100978582; called by muse, mutect2, varscan2
- GRM1 | c.3301G>T p.E1101* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV99265170; called by muse, mutect2, varscan2
- GUCY2C | c.2693T>A p.L898* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV99663443; called by muse, mutect2, varscan2
- GYS2 | c.2108A>G p.N703S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs1293044624, COSV99679608; called by muse, mutect2, varscan2
- HAND2 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100854169; called by muse, mutect2, varscan2
- HCN1 | c.1609T>A p.Y537N | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100299481; called by muse, varscan2
- HCN1 | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 92/138 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV100299484; called by muse, varscan2
- HDC | c.1685A>G p.K562R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99983923; called by muse, mutect2, varscan2
- HDC | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV51069327, COSV51077289; called by muse, mutect2
- HEATR5B | c.4264G>T p.V1422F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99248801; called by muse, mutect2, varscan2
- HLA-G | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV100827035; called by muse, mutect2, varscan2
- HPSE | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV100264219; called by muse, mutect2, varscan2
- HUWE1 | c.3103A>T p.K1035* | Nonsense Mutation (SNP) | VAF 36/115 reads (31%) | catalogued as COSV99471364; called by muse, mutect2, varscan2
- ICAM5 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV99320653; called by muse, mutect2, varscan2
- IGF2BP1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs1024617698, COSV51736242; called by muse, mutect2
- IGKV1-9 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as rs976312466; called by muse, mutect2, varscan2
- IGLV1-51 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781370509; called by muse, mutect2, varscan2
- IL1RAPL1 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100146318; called by muse, mutect2, varscan2
- IL27 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs752031519, COSV100112394; called by muse, mutect2, varscan2
- IMPDH1 | c.416C>G p.S139C (on ENST00000470772 / NM_001142573.2; = p.S225C on NM_000883.4) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV100118638; called by muse, mutect2
- INPP5D | c.1880A>T p.Q627L (on ENST00000445964 / NM_001017915.3; = p.Q626L on NM_005541.5) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV100856639; called by muse, mutect2, varscan2
- INTS10 | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778694702, COSV101208664; called by muse, mutect2, varscan2
- ITPR1 | c.4729T>C p.W1577R (on ENST00000354582; = p.W1562R on NM_002222.7) | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV100230513; called by muse, mutect2, varscan2
- ITPR3 | c.5644G>C p.E1882Q | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100967175; called by muse, mutect2, varscan2
- JAK2 | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV101072008; called by muse, mutect2, varscan2
- KCTD18 | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs1432509274, COSV100728849; called by muse, mutect2, varscan2
- KIAA1522 | c.1706C>T p.S569F (on ENST00000373480 / NM_001198972.2; = p.S628F on NM_020888.3) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99614384; called by muse, mutect2, varscan2
- KLHL34 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV101069964, COSV65279859; called by muse, mutect2, varscan2
- KLK2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.1); catalogued as COSV100319895; called by muse, mutect2, varscan2
- KMT2A | c.3341C>T p.S1114L | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100628056; called by muse, mutect2, varscan2
- KRT1 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV99358619; called by muse, mutect2, varscan2
- KRT39 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100842177, COSV62918245; called by muse, mutect2, varscan2
- KRT8 | c.1136A>C p.N379T | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV99509958; called by muse, mutect2, varscan2
- KRT81 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1380424967, COSV100576956; called by muse, mutect2, varscan2
- KRTAP20-1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/67 reads (45%) | PolyPhen benign (0.378); catalogued as COSV100228730; called by muse, mutect2, varscan2
- LAMA2 | c.7210C>A p.L2404M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370277; called by muse, mutect2, varscan2
- LGI3 | c.512C>G p.S171* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100102944; called by muse, mutect2, varscan2
- LILRB4 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99553662; called by muse, mutect2, varscan2
- LIN54 | c.1720A>T p.R574* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100464405; called by muse, mutect2, varscan2
- LNX1 | c.1009C>G p.H337D (on ENST00000263925 / NM_001126328.3; = p.H241D on NM_032622.2) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55793977; called by muse, mutect2
- LRIT2 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV60559996; called by muse, mutect2, varscan2
- LRRN2 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs780674784, COSV100912796; called by muse, mutect2, varscan2
- LYST | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as rs1398467049, COSV101088824; called by muse, mutect2, varscan2
- MADD | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as rs768316614, COSV100211263; called by muse, mutect2, varscan2
- MAGEB16 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV101303291, COSV67874286; called by muse, mutect2, varscan2
- MAGEE1 | c.1500G>C p.Q500H | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100819345, COSV100819407; called by muse, mutect2
- MAP11 | c.512T>A p.V171E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV100385421; called by muse, mutect2, varscan2
- MAP3K13 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV53992585; called by muse, mutect2, varscan2
- MAP4 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 81/143 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV100805554; called by muse, mutect2, varscan2
- MARK2 | c.1526C>T p.P509L (on ENST00000402010 / NM_001039469.2; = p.P475L on NM_017490.4) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV100158343; called by muse, mutect2, varscan2
- MASP1 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100537082; called by muse, mutect2, varscan2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MCCC1 | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55610400, COSV99659528; called by muse, mutect2, varscan2
- MCF2 | c.143G>C p.S48T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV100644639; called by muse, mutect2, varscan2
- MCTP2 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100537359; called by muse, mutect2, varscan2
- MED12L | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs948152079, COSV56400122, COSV99852246; called by muse, mutect2, varscan2
- MED21 | c.158-1G>C p.X53_splice | Splice Site (SNP) | VAF 41/116 reads (35%) | catalogued as COSV99282040; called by muse, mutect2, varscan2
- MINDY3 | c.1245G>C p.Q415H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.598); catalogued as COSV99510621; called by muse, mutect2, varscan2
- MLXIPL | c.1956C>G p.I652M | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV100515253; called by muse, mutect2, varscan2
- MMRN1 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as rs762583168, COSV99306823; called by muse, mutect2, varscan2
- MORC4 | c.1130A>T p.Q377L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99717001; called by muse, mutect2, varscan2
- MSANTD4 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.102); catalogued as COSV100108561; called by muse, mutect2, varscan2
- MUC16 | c.26680A>G p.T8894A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.042); catalogued as COSV101199147; called by muse, mutect2, varscan2
- MUC16 | c.16292G>T p.G5431V | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.073); catalogued as COSV101199148; called by muse, mutect2, varscan2
- MUC17 | c.3635C>G p.S1212* | Nonsense Mutation (SNP) | VAF 134/364 reads (37%) | catalogued as rs767371089, COSV100072512; called by muse, mutect2, varscan2
- MVD | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99964777; called by muse, mutect2, varscan2
- MYH4 | c.5098G>A p.E1700K | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99700744; called by muse, varscan2
- NCAPG2 | c.1635G>C p.Q545H | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99316739; called by muse, mutect2, varscan2
- NCF4 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99957217; called by muse, mutect2, varscan2
- NCKAP1L | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs367688748; called by muse, mutect2, varscan2
- NCKAP5 | c.2286G>C p.R762S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100490975; called by muse, mutect2, varscan2
- NECTIN4 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100919860; called by muse, mutect2
- NEDD1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.556); catalogued as COSV57143876; called by muse, mutect2, varscan2
- NEXMIF | c.4406G>T p.R1469L | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50088606, COSV99280286; called by muse, mutect2, varscan2
- NINL | c.919T>G p.S307A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.081); catalogued as COSV99625021; called by muse, mutect2, varscan2
- NLRP12 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as rs370373416; called by muse, mutect2, varscan2
- NLRP8 | c.2534+2T>A p.X845_splice | Splice Site (SNP) | VAF 22/88 reads (25%) | catalogued as COSV99404990; called by muse, mutect2, varscan2
- NOS1AP | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as COSV100723027; called by muse, mutect2, varscan2
- NOS2 | c.3026G>C p.R1009P | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs762167122, COSV100569562, COSV100569889; called by muse, mutect2, varscan2
- NOVA1 | c.1404G>C p.R468S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV99947027; called by muse, mutect2, varscan2
- NRP2 | c.853T>C p.S285P | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99783880; called by muse, mutect2, varscan2
- NSMCE3 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs915659811, COSV99721439; called by muse, mutect2, varscan2
- NUP153 | c.2603C>G p.S868C | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV100020064; called by muse, mutect2, varscan2
- NUP210L | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.997); catalogued as COSV55151744, COSV99667613; called by muse, mutect2, varscan2
- OR10G4 | c.324C>A p.S108R | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV100304766; called by muse, mutect2, varscan2
- OR10K2 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149377, COSV59221829; called by muse, mutect2, varscan2
- OR11G2 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV100639929; called by muse, mutect2, varscan2
- OR12D2 | c.693C>A p.S231R | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV101011184; called by muse, mutect2, varscan2
- OR2M2 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 192/405 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.463); catalogued as COSV100677208; called by muse, mutect2, varscan2
- OR2M7 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.657); catalogued as COSV100522481, COSV58739346, COSV58740791; called by muse, mutect2, varscan2
- OR4C12 | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV100078397; called by muse, mutect2, varscan2
- OR5AC2 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100684336; called by muse, mutect2, varscan2
- OR5H1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs775826333, COSV100641656, COSV63402017; called by muse, mutect2, varscan2
- OR5H6 | c.470G>C p.C157S (on ENST00000642105; = p.C141S on NM_001005479.2) | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67350988; called by muse, mutect2, varscan2
- OR6K6 | c.245C>T p.A82V (on ENST00000368144; = p.A58V on NM_001005184.1) | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV100933715; called by muse, mutect2, varscan2
- OR8B4 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100635781; called by muse, mutect2
- OTOA | c.2030C>T p.S677L (on ENST00000286149; = p.S663L on NM_144672.4) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV53750245; called by muse, mutect2, varscan2
- PCDH19 | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.438); catalogued as COSV99719388; called by muse, mutect2, varscan2
- PCDHB14 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV99505706; called by muse, mutect2, varscan2
- PCDHB3 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV50565386; called by muse, mutect2, varscan2
- PCDHB8 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV99176506; called by muse, mutect2, varscan2
- PCDHGA11 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.196); catalogued as rs752366104, COSV99534340; called by muse, mutect2, varscan2
- PCDHGB6 | c.2282C>T p.T761I | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV99534338; called by muse, mutect2, varscan2
- PCNX2 | c.6347G>C p.R2116T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV99266744; called by muse, mutect2
- PCNX3 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.952); catalogued as COSV100482358; called by muse, mutect2, varscan2
- PCNX3 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs946620141, COSV58421592; called by muse, mutect2, varscan2
- PEAR1 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99441011; called by muse, mutect2
- PES1 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100073061, COSV58828146; called by muse, mutect2, varscan2
- PEX5L | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.107); catalogued as rs201063859, COSV99828321; called by muse, mutect2, varscan2
- PFKFB1 | c.1408C>A p.H470N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | PolyPhen possibly damaging (0.851); catalogued as COSV51506907, COSV99436111; called by muse, mutect2, varscan2
- PHIP | c.4640A>G p.N1547S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.956); catalogued as COSV99243722; called by muse, mutect2
- PIK3R5 | c.2494A>T p.R832* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99353103; called by muse, mutect2, varscan2
- PLK4 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99584533; called by muse, mutect2, varscan2
- PLPPR5 | c.370+2T>A p.X124_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99587132; called by muse, mutect2, varscan2
- PLXNB2 | c.3818C>T p.P1273L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833957; called by muse, mutect2, varscan2
- PNPO | c.628G>A p.D210N (on ENST00000225573; = p.D253N on NM_018129.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99846482; called by muse, mutect2, varscan2
- POLE | c.3376G>T p.A1126S | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs1555225288, COSV100265879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POPDC3 | c.280C>A p.H94N | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99633554; called by muse, mutect2, varscan2
- POTEE | c.1702G>T p.G568* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100387433; called by muse, mutect2, varscan2
- PPEF1 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100583645, COSV62995701, COSV62995999; called by muse, mutect2, varscan2
- PRICKLE3 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100889901; called by muse, mutect2, varscan2
- PRKD2 | c.1122-1G>A p.X374_splice | Splice Site (SNP) | VAF 26/55 reads (47%) | catalogued as COSV99354191; called by muse, mutect2, varscan2
- PROSER1 | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); catalogued as COSV100612724; called by muse, mutect2, varscan2
- R3HDM2 | c.1743G>C p.Q581H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100715023; called by muse, mutect2, varscan2
- RAB36 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99572158; called by muse, mutect2, varscan2
- RASL12 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369491615; called by muse, mutect2, varscan2
- RGL1 | c.1640C>G p.S547C (on ENST00000360851 / NM_001297672.2; = p.S582C on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV100486375; called by muse, mutect2, varscan2
- RGS22 | c.3277C>T p.Q1093* | Nonsense Mutation (SNP) | VAF 41/138 reads (30%) | catalogued as COSV100693122; called by muse, mutect2, varscan2
- RNF17 | c.1336A>T p.K446* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99692695; called by muse, mutect2, varscan2
- ROCK1 | c.3780G>T p.E1260D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101296301; called by muse, mutect2, varscan2
- RXFP2 | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV100034179; called by muse, mutect2, varscan2
- RYR2 | c.3819A>G p.I1273M | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); catalogued as COSV100769083; called by muse, mutect2, varscan2
- SAMD8 | c.356G>A p.C119Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101014014; called by muse, mutect2, varscan2
- SASS6 | c.1733G>C p.G578A | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99790726; called by muse, mutect2, varscan2
- SCN1A | c.3452C>T p.S1151L (on ENST00000303395 / NM_001202435.3; = p.S1140L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs1305709501, CM096101, COSV100319868; called by muse, mutect2, varscan2
- SCN2A | c.4853A>G p.Y1618C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99330832; called by muse, mutect2, varscan2
- SENP1 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV99136857; called by muse, mutect2
- SENP7 | c.2104C>G p.Q702E | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV100052779; called by muse, mutect2, varscan2
- SERHL2 | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV100243499; called by muse, mutect2, varscan2
- SHLD2 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV100079042; called by muse, mutect2, varscan2
- SHROOM2 | c.4195T>G p.Y1399D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101098383; called by muse, mutect2, varscan2
- SI | c.2689C>G p.Q897E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV52264441, COSV52266126; called by muse, mutect2, varscan2
- SIGLEC11 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV101389218; called by muse, mutect2, varscan2
- SIGLEC8 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100367206, COSV58471655; called by muse, mutect2, varscan2
- SKI | c.354G>C p.E118D | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV101049302, COSV66014404; called by muse, mutect2, varscan2
- SLC10A4 | c.759C>A p.F253L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99906812; called by muse, mutect2, varscan2
- SLC12A6 | c.2294T>A p.L765Q (on ENST00000354181 / NM_001365088.1; = p.L714Q on NM_005135.2) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99271448; called by muse, mutect2
- SLC13A1 | c.1298G>A p.W433* | Nonsense Mutation (SNP) | VAF 26/135 reads (19%) | catalogued as COSV52013208, COSV99520674; called by muse, mutect2, varscan2
- SLC24A1 | c.3023G>T p.G1008V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99978147; called by muse, mutect2, varscan2
- SLC5A12 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV101237658; called by muse, mutect2, varscan2
- SLC8A1 | c.2355G>T p.W785C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245419, COSV60479185; called by muse, varscan2
- SLC9A2 | c.1831C>G p.Q611E | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs777672924, COSV99296048; called by muse, mutect2, varscan2
- SLCO2A1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs747030503, COSV100188692, COSV60487005; called by muse, mutect2, varscan2
- SLPI | c.101T>A p.V34D | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.472); catalogued as COSV100619750; called by muse, mutect2, varscan2
- SMPD1 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV100192543; called by muse, mutect2, varscan2
- SNRK | c.1368G>C p.K456N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs772301139, COSV99938973; called by muse, mutect2, varscan2
- SNX19 | c.567G>T p.W189C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148379069; called by muse, mutect2, varscan2
- SNX29 | c.329C>A p.S110* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV101625437, COSV73754436; called by muse, mutect2, varscan2
- SOX30 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 32/60 reads (53%) | catalogued as COSV53937415, COSV99398295; called by muse, varscan2
- SP4 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99754265; called by muse, mutect2, varscan2
- SPATA33 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs751571842, COSV99498320; called by muse, varscan2
- SPEN | c.4169C>A p.S1390Y | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as COSV101005094; called by muse, mutect2, varscan2
- SPTA1 | c.5732C>A p.P1911H | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV100934659, COSV63753611; called by muse, mutect2, varscan2
- SPTA1 | c.5731C>A p.P1911T | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV100934660; called by muse, mutect2, varscan2
- SPTA1 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1049898003, COSV63757443; called by muse, mutect2, varscan2
- SRGN | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54344721; called by muse, mutect2, varscan2
- SRSF11 | c.748A>G p.R250G | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV100917845; called by muse, mutect2, varscan2
- SSH1 | c.2777C>G p.S926C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100425420; called by muse, mutect2, varscan2
- STK32C | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100062132; called by muse, mutect2, varscan2
- STOX1 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100057696; called by muse, mutect2, varscan2
- SVEP1 | c.9507G>T p.W3169C | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928676, COSV99929872; called by muse, mutect2, varscan2
- SYNE1 | c.16706A>G p.H5569R (on ENST00000367255 / NM_182961.4; = p.H5498R on NM_033071.3) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV99558340; called by muse, mutect2, varscan2
- TBC1D25 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100952121; called by muse, mutect2
- TGFBR3 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99282699; called by muse, mutect2, varscan2
- TMEM230 | c.68C>G p.S23C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1411906884, COSV99176955; called by muse, mutect2, varscan2
- TNFRSF10D | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 6/9 reads (67%) | catalogued as COSV100441674; called by muse, mutect2, varscan2
- TNIK | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV52681081, COSV99456172; called by muse, mutect2, varscan2
- TP63 | c.1411A>G p.S471G | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99286283; called by muse, mutect2, varscan2
- TPM2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100253119; called by muse, mutect2, varscan2
- TRIM42 | c.2139G>C p.K713N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99648178; called by muse, mutect2, varscan2
- TRO | c.3984C>A p.D1328E | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV51497801; called by muse, mutect2, varscan2
- TRPM3 | c.4435G>A p.D1479N (on ENST00000357533 / NM_001366142.2; = p.D1334N on NM_020952.6) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.056); catalogued as COSV100677060; called by muse, mutect2, varscan2
- TRPS1 | c.887C>G p.S296C (on ENST00000220888 / NM_001330599.2; = p.S309C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV55233208, COSV99629580; called by muse, mutect2, varscan2
- TSSK3 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100344504, COSV61982549; called by muse, mutect2, varscan2
- TTN | c.65783T>A p.I21928N (on ENST00000591111; = p.I14504N on NM_003319.4) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | PolyPhen possibly damaging (0.837); catalogued as COSV100602727; called by muse, mutect2, varscan2
- TTN | c.55817G>C p.R18606T (on ENST00000591111; = p.R11182T on NM_003319.4) | Missense Mutation (SNP) | VAF 57/189 reads (30%) | PolyPhen benign (0.098); catalogued as rs1476856391, COSV100602728; called by muse, mutect2, varscan2
- TTN | c.54770G>C p.W18257S (on ENST00000591111; = p.W10833S on NM_003319.4) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | PolyPhen probably damaging (0.998); catalogued as COSV100602732; called by muse, mutect2, varscan2
- TTN | c.46249G>C p.D15417H (on ENST00000591111; = p.D7993H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | PolyPhen possibly damaging (0.551); catalogued as COSV100602733; called by muse, mutect2, varscan2
- TTN | c.35005C>A p.P11669T (on ENST00000591111; = p.P10742T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | PolyPhen benign (0.015); catalogued as rs748880548, COSV100602735, COSV59951001; called by muse, mutect2, varscan2
- TUB | c.85C>G p.R29G (on ENST00000299506 / NM_177972.3; = p.R84G on NM_003320.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV100210125, COSV55107942; called by muse, mutect2, varscan2
- UFL1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100990038; called by muse, varscan2
- UNC119 | c.609G>C p.L203= | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99971647; called by muse, mutect2
- UNC79 | c.4804A>G p.K1602E (on ENST00000393151 / NM_001346218.2; = p.K1425E on NM_020818.5) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV99826717; called by muse, mutect2, varscan2
- UPP2 | c.371T>C p.M124T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99134770; called by muse, mutect2, varscan2
- UROD | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV99870041; called by muse, mutect2, varscan2
- USP38 | c.2439C>G p.F813L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100189166; called by muse, mutect2, varscan2
- VAV1 | c.1898A>G p.E633G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs914814433, COSV100408836; called by muse, mutect2, varscan2
- WAS | c.275C>A p.A92D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.048); catalogued as COSV100939464; called by muse, mutect2, varscan2
- WDPCP | c.1746C>G p.L582= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99704679; called by muse, mutect2, varscan2
- XYLT2 | c.1739T>G p.L580R | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV99190821; called by muse, mutect2, varscan2
- ZBTB20 | c.1810A>G p.K604E (on ENST00000474710 / NM_001164342.2; = p.K531E on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100613292; called by muse, mutect2, varscan2
- ZC3H12A | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100897677; called by muse, mutect2
- ZFP91 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs376871246; called by muse, mutect2, varscan2
- ZFP91 | c.1703C>G p.A568G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100284417; called by muse, mutect2, varscan2
- ZFPM1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100128299; called by muse, mutect2, varscan2
- ZMYM1 | c.1749A>T p.K583N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100720933; called by muse, mutect2, varscan2
- ZMYM3 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183761610, COSV100077659; called by muse, mutect2, varscan2
- ZNF136 | c.653A>C p.H218P | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100677917; called by muse, mutect2
- ZNF148 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV100642036; called by muse, mutect2, varscan2
- ZNF202 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100278968; called by muse, mutect2, varscan2
- ZNF257 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1222719287, COSV101448072; called by muse, mutect2, varscan2
- ZNF3 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52796554, COSV99447167; called by muse, mutect2, varscan2
- ZNF34 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100603250; called by muse, mutect2, varscan2
- ZNF462 | c.5918G>C p.C1973S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99471232; called by muse, mutect2, varscan2
- ZNF518A | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100283427; called by muse, mutect2, varscan2
- ZNF655 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99402026; called by muse, varscan2
- ZNF655 | c.1279C>G p.H427D | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99402028; called by muse, varscan2
- ZNF681 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV68074203, COSV68075670; called by muse, mutect2
- ZNF711 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.562); catalogued as COSV99340840; called by mutect2, varscan2
- ZSCAN16 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 103/167 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.486); catalogued as COSV100481471; called by muse, mutect2, varscan2
- ARHGAP22 | c.139del p.Q47Rfs*5 | Frame Shift Del (DEL) | VAF 24/150 reads (16%) | called by mutect2, pindel*, varscan2
- CPNE3 | c.999dup p.Q334Sfs*4 | Frame Shift Ins (INS) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- CYP1A1 | c.1302_1304dup p.P435dup | In Frame Ins (INS) | VAF 37/100 reads (37%) | called by mutect2, pindel, varscan2
- EBI3 | c.264C>G p.S88R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HYOU1 | c.2815dup p.E939Gfs*11 | Frame Shift Ins (INS) | VAF 62/160 reads (39%) | called by mutect2, pindel, varscan2
- IGHV3-23 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 41/423 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- KCNA4 | c.1267del p.L423Wfs*59 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- MORF4L1 | c.495_497del p.S166del (on ENST00000331268 / NM_206839.2; = p.S127del on NM_006791.4) | In Frame Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- PCDHB14 | c.297del p.E100Sfs*27 | Frame Shift Del (DEL) | VAF 48/129 reads (37%) | called by mutect2, pindel, varscan2
- PCDHGB5 | c.1062A>C p.E354D | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POMC | c.34del p.L12Cfs*59 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- POTEA | c.919C>A p.L307M (on ENST00000519951 / NM_001005365.2; = p.L261M on NM_001002920.1) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TCTEX1D2 | c.338G>C p.W113S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCG8 | c.402C>A p.I134= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99699614; called by muse, mutect2, varscan2
- ACTN2 | c.2046G>A p.E682= | Silent (SNP) | VAF 73/173 reads (42%) | catalogued as COSV100856676; called by muse, mutect2, varscan2
- ADAMTS18 | c.3588C>T p.H1196= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs752084827, COSV51400457, COSV99271867, COSV99271979; called by muse, mutect2, varscan2
- ADCY10 | c.2826C>G p.L942= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100896701; called by muse, mutect2, varscan2
- ANO4 | c.2475C>A p.A825= (on ENST00000392977 / NM_001286615.2; = p.A790= on NM_178826.4) | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as COSV100152469; called by muse, mutect2, varscan2
- APH1A | c.39G>T p.A13= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99354321; called by muse, mutect2, varscan2
- ARRDC4 | c.1029G>C p.L343= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99164337; called by muse, mutect2, varscan2
- ASTE1 | c.1350G>A p.V450= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs556717620, COSV99393730; called by muse, mutect2, varscan2
- ASTN1 | c.1902C>T p.L634= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99920983; called by muse, mutect2, varscan2
- ATRX | c.4551G>A p.L1517= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV100970395; called by muse, mutect2, varscan2
- BIRC6 | c.2160G>A p.L720= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV70200882; called by muse, mutect2, varscan2
- BMPR1A | c.1545G>A p.L515= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100923409; called by muse, mutect2, varscan2
- C2orf88 | c.168T>A p.T56= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV100502735, COSV100502814; called by muse, mutect2, varscan2
- CAPN13 | c.1338C>T p.T446= | Silent (SNP) | VAF 63/185 reads (34%) | catalogued as rs988779405, COSV99700027; called by muse, mutect2, varscan2
- CCDC184 | c.93G>C p.V31= | Silent (SNP) | VAF 161/207 reads (78%) | catalogued as COSV100343946, COSV57252258; called by muse, mutect2, varscan2
- CCDC33 | c.1845G>T p.S615= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV99173229; called by muse, mutect2, varscan2
- CCHCR1 | c.612G>C p.L204= | Silent (SNP) | VAF 115/173 reads (66%) | catalogued as COSV100885600, COSV66185111; called by muse, mutect2, varscan2
- CD53 | c.516G>A p.A172= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs768034243, COSV54760709; called by muse, mutect2, varscan2
- CENPJ | c.2307C>A p.I769= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as COSV101121483; called by muse, mutect2, varscan2
- CPS1 | c.4482C>T p.Y1494= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as rs769692031, COSV99242574; called by muse, mutect2, varscan2
- CRNN | c.381G>C p.G127= | Silent (SNP) | VAF 98/314 reads (31%) | catalogued as rs879215940, COSV55120893, COSV99664032; called by muse, mutect2, varscan2
- DOCK3 | c.1923G>A p.L641= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV99810467; called by muse, mutect2, varscan2
- DRP2 | c.2118G>T p.P706= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV100871852, COSV65812002; called by muse, mutect2, varscan2
- DUSP10 | c.897C>A p.G299= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100100279, COSV60458316; called by muse, mutect2, varscan2
- DUSP21 | c.357G>T p.A119= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100173537, COSV59133701; called by muse, mutect2, varscan2
- EDEM2 | c.27C>A p.L9= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100993703, COSV100993859; called by muse, mutect2, varscan2
- EHMT1 | c.3762C>T p.F1254= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1224603807, COSV66044703; called by muse, mutect2, varscan2
- EIF2B2 | c.54C>T p.F18= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1038490990, COSV99837651; called by muse, mutect2, varscan2
- ESYT1 | c.255C>T p.L85= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs80169445, COSV57271572, COSV57276066; called by muse, mutect2, varscan2
- FABP7 | c.165C>A p.L55= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100737923; called by muse, mutect2, varscan2
- FBXO3 | c.168T>C p.H56= | Silent (SNP) | VAF 14/296 reads (5%) | catalogued as COSV99682132; called by muse, mutect2
- FLACC1 | c.483C>T p.L161= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV53783511, COSV99630010; called by muse, mutect2, varscan2
- FRRS1L | c.531T>C p.N177= | Silent (SNP) | VAF 93/155 reads (60%) | catalogued as rs769545466, COSV101643903; ClinVar: likely benign; called by muse, mutect2, varscan2
- FTCD | c.1500C>T p.I500= | Silent (SNP) | VAF 39/67 reads (58%) | catalogued as rs768207177, COSV99384823; called by muse, mutect2, varscan2
- FTHL17 | c.384C>G p.P128= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100784267; called by muse, mutect2, varscan2
- GINS3 | c.606C>T p.L202= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs770818447, COSV100139251; called by muse, mutect2, varscan2
- GOLGB1 | c.9003C>G p.L3001= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs1451717131, COSV61461974; called by muse, mutect2, varscan2
- GRM8 | c.246A>T p.A82= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100281716; called by muse, mutect2, varscan2
- GUCY2D | c.1416G>T p.L472= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV99643864; called by muse, mutect2, varscan2
- HS3ST3A1 | c.588C>T p.L196= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1232076022, COSV52372901; called by muse, mutect2, varscan2
- HSPG2 | c.12864C>T p.I4288= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100760742; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.33G>T p.V11= | Silent (SNP) | VAF 35/237 reads (15%) | called by muse, mutect2, varscan2
- INPP5D | c.1881G>A p.Q627= (on ENST00000445964 / NM_001017915.3; = p.Q626= on NM_005541.5) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100856640; called by muse, mutect2, varscan2
- KATNAL2 | c.603C>G p.T201= (on ENST00000356157 / NM_001353899.1; = p.T129= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99796259; called by muse, mutect2, varscan2
- KATNAL2 | c.1317G>C p.V439= (on ENST00000356157 / NM_001353899.1; = p.V367= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99796260; called by muse, mutect2, varscan2
- KHDC1 | c.711G>A p.P237= (on ENST00000370384 / NM_001251874.2; = p.P164= on NM_030568.5) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs182325320; called by muse, mutect2, varscan2
- KIF4A | c.414G>T p.V138= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as COSV100979461; called by muse, mutect2, varscan2
- KIRREL3 | c.2046G>C p.L682= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV101375184; called by muse, mutect2, varscan2
- KMT2A | c.9862A>C p.R3288= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as COSV100628402; called by muse, mutect2
- LRRC46 | c.582C>T p.F194= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99274021; called by muse, mutect2, varscan2
- LRRTM3 | c.900T>A p.S300= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV100791558; called by muse, mutect2, varscan2
- LTBP2 | c.2709C>A p.I903= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99999997; called by muse, mutect2, varscan2
- MAGIX | c.264G>A p.V88= | Silent (SNP) | VAF 37/147 reads (25%) | catalogued as COSV100891856; called by muse, mutect2, varscan2
- MAN2B2 | c.1878G>A p.V626= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as COSV53453140; called by muse, mutect2, varscan2
- MAP3K12 | c.2446C>T p.L816= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99913106; called by muse, mutect2, varscan2
- MEF2C | c.132G>A p.A44= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs776920242, COSV100425047; ClinVar: likely benign; called by muse, mutect2, varscan2
- MID2 | c.597G>A p.E199= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99464321; called by muse, mutect2, varscan2
- MYO7B | c.1299C>T p.I433= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs780212337, COSV67344073, COSV67346089; called by muse, mutect2, varscan2
- NAB1 | c.813T>G p.L271= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100492928; called by muse, mutect2, varscan2
- NEIL3 | c.126C>G p.L42= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV52814334, COSV99220169; called by muse, mutect2, varscan2
- NPAS4 | c.963C>T p.S321= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100214897; called by muse, mutect2, varscan2
- NR2F2 | c.309C>T p.F103= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV101240979, COSV67683084; called by muse, mutect2, varscan2
- NRROS | c.750C>T p.F250= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100145424; called by muse, mutect2, varscan2
- NUP160 | c.3666G>T p.A1222= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs541752129, COSV101021402; called by muse, mutect2, varscan2
- NXF1 | c.816G>A p.L272= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99585906; called by muse, mutect2, varscan2
- OASL | c.354G>A p.L118= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as COSV99984453, COSV99984482; called by muse, mutect2, varscan2
- OR2B6 | c.792G>T p.S264= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as COSV99773670; called by muse, varscan2
- OR2T27 | c.477C>T p.L159= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100788180; called by mutect2, varscan2
- OR5A1 | c.822C>T p.D274= | Silent (SNP) | VAF 41/133 reads (31%) | catalogued as COSV100118323; called by muse, mutect2, varscan2
- PDK4 | c.642C>G p.L214= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV99138767; called by muse, mutect2, varscan2
- PIM2 | c.237A>C p.T79= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99900073; called by muse, mutect2, varscan2
- PITPNB | c.324C>T p.F108= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100087098; called by muse, mutect2
- PKD2 | c.1840T>C p.L614= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99417082; called by muse, mutect2, varscan2
- PLXNB2 | c.4323G>A p.Q1441= | Silent (SNP) | VAF 89/174 reads (51%) | catalogued as COSV100833955; called by muse, mutect2, varscan2
- PPP3R2 | c.39C>A p.S13= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100701429; called by muse, mutect2, varscan2
- PRDM15 | c.405C>A p.L135= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV99519708; called by muse, mutect2, varscan2
- PTPRF | c.543C>T p.N181= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs372286913; called by muse, mutect2, varscan2
- RBL2 | c.1815C>G p.L605= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100043454; called by muse, mutect2, varscan2
- RNF17 | c.1335G>A p.E445= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99692691; called by muse, mutect2, varscan2
- RPS20 | c.204T>A p.T68= | Silent (SNP) | VAF 7/122 reads (6%) | catalogued as COSV99154818; called by muse, mutect2
- SDK1 | c.2190G>A p.V730= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as rs1003805808, COSV101269060; called by muse, mutect2, varscan2
- SEPTIN4 | c.48G>A p.Q16= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV100400274; called by muse, mutect2, varscan2
- SKIV2L | c.2238C>T p.L746= | Silent (SNP) | VAF 57/91 reads (63%) | catalogued as COSV100514617; called by muse, mutect2, varscan2
- SLC66A3 | c.216C>T p.L72= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV99706142; called by muse, mutect2, varscan2
- SLC6A5 | c.432C>T p.N144= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100116659; called by muse, mutect2
- SPAG5 | c.2472G>A p.L824= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100410512; called by muse, mutect2, varscan2
- SRRM2 | c.7024C>A p.R2342= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as COSV51940080, COSV99241340; called by muse, mutect2, varscan2
- STXBP2 | c.615C>T p.V205= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as COSV99657063; called by muse, mutect2, varscan2
- TAF1 | c.3591G>A p.R1197= (on ENST00000373790 / NM_138923.4; = p.R1218= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99335169; called by muse, mutect2, varscan2
- TAS2R60 | c.309G>T p.L103= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as COSV60330311; called by muse, mutect2, varscan2
- TCEA1 | c.303T>A p.P101= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV101124260; called by muse, mutect2, varscan2
- TDRD7 | c.2823G>C p.L941= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV62431112; called by muse, mutect2, varscan2
- THRSP | c.102C>T p.P34= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as COSV99806450; called by muse, mutect2, varscan2
- THSD7A | c.3177T>C p.S1059= | Silent (SNP) | VAF 116/194 reads (60%) | catalogued as COSV101448603; called by muse, mutect2, varscan2
- THSD7A | c.2835C>T p.S945= | Silent (SNP) | VAF 62/99 reads (63%) | catalogued as COSV101448604; called by muse, mutect2, varscan2
- TMEM132D | c.3147C>T p.T1049= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV101242675; called by muse, mutect2, varscan2
- TMEM270 | c.85C>A p.R29= | Silent (SNP) | VAF 244/537 reads (45%) | catalogued as rs781996746, COSV100260317; called by muse, mutect2, varscan2
- TNK2 | c.480G>A p.L160= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV57365984; called by muse, mutect2, varscan2
- TRBC2 | c.303C>T p.Y101= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs531326996; called by muse, mutect2, varscan2
- TRIM36 | c.171A>G p.V57= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as rs1301471339, COSV99142310; called by muse, mutect2, varscan2
- TROAP | c.1902G>T p.G634= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99226741; called by muse, mutect2, varscan2
- TRPC5 | c.1428G>A p.L476= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV53291296; called by muse, mutect2, varscan2
- TRPM2 | c.2859G>A p.Q953= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- TTC27 | c.1011G>C p.P337= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV100512832; called by muse, mutect2, varscan2
- TTLL1 | c.48G>C p.L16= | Silent (SNP) | VAF 49/274 reads (18%) | catalogued as COSV99840243; called by muse, mutect2, varscan2
- TTN | c.26688G>T p.P8896= (on ENST00000591111; = p.P7969= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100602739, COSV59872999; called by muse, mutect2, varscan2
- TTN | c.25257A>G p.P8419= (on ENST00000591111; = p.P7492= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100602740; called by muse, mutect2, varscan2
- ZBBX | c.1764A>G p.T588= | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as rs1275857771, COSV100283614; called by muse, mutect2, varscan2
- ZBTB34 | c.816G>T p.V272= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100043627; called by muse, mutect2, varscan2
- ZNF721 | c.387A>G p.E129= (on ENST00000338977; = p.E141= on NM_133474.4) | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100167259; called by muse, mutect2
- ZNF804A | c.1557A>G p.K519= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100167168; called by muse, mutect2, varscan2
- ZNF804A | c.2440C>A p.R814= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs772974941, COSV56437401, COSV56474195; called by muse, mutect2, varscan2
- ZNF846 | c.636C>T p.S212= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs1388940910, COSV67412246; called by muse, mutect2, varscan2
- ACAD9 | c.*192A>G | 3'UTR (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100459053; called by muse, mutect2, varscan2
- AFDN | chr6:167826222 G>C | 5'Flank (SNP) | VAF 50/143 reads (35%) | called by muse, mutect2, varscan2
- NPHS1 | c.*1G>T | 3'UTR (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100799688; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120918 G>T | 3'Flank (SNP) | VAF 13/43 reads (30%) | catalogued as rs748157796; called by muse, mutect2, varscan2
- PML | c.1710+1486C>G | Intron (SNP) | VAF 67/197 reads (34%) | catalogued as COSV51449845, COSV99166836; called by muse, mutect2, varscan2
- RPGR | c.2520+1405C>T | Intron (SNP) | VAF 50/190 reads (26%) | catalogued as COSV100139784, COSV58833511; called by muse, mutect2, varscan2
- TMEM107 | c.*681G>C | 3'UTR (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100328711; called by muse, mutect2, varscan2
- TTN | c.10360+2439G>C | Intron (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100602741; called by mutect2, varscan2
